Somatic mutation profile of tumor specimen TARGET-10-PAUBPY-09A (aliquot TARGET-10-PAUBPY-09A-01D) from TARGET case TARGET-10-PAUBPY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.6 years (4,219 days).
Specimen TARGET-10-PAUBPY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0661f293-d227-427c-8dd5-a52e434e3c94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUBPY-10A (Blood Derived Normal), aliquot TARGET-10-PAUBPY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d567cc4-c8d6-4710-936d-dde3487d09de

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Nonsense Mutation 2, In Frame Ins 2, 3'UTR 2, Frame Shift Ins 2, Intron 1, Splice Region 1, Frame Shift Del 1, RNA 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.2387A>G p.E796G | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as COSV62811435; called by muse, mutect2, varscan2
- ARHGAP39 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.072); catalogued as rs367945395; called by muse, mutect2, varscan2
- ATP9B | c.3039C>A p.F1013L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV56946786; called by muse, mutect2, varscan2
- ATRNL1 | c.2412A>C p.Q804H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV61798017; called by muse, mutect2
- EZH2 | c.1673C>T p.P558L (on ENST00000460911 / NM_001203247.2; = p.P563L on NM_004456.5) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV57447401; called by muse, mutect2, varscan2
- HCN2 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52112709; called by muse, mutect2, varscan2
- IL7R | c.727_728insGTCGCC p.L242_L243insRR | In Frame Ins (INS) | VAF 32/68 reads (47%) | catalogued as COSV57405510, COSV57408205, COSV57408696, COSV57410138, COSV57410369, COSV57415525, COSV99073416; called by mutect2, pindel, varscan2
- ITSN1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67156895; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- KRT40 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.205); catalogued as rs754195698, COSV66696032; called by muse, mutect2, varscan2
- MMEL1 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 56/111 reads (50%) | catalogued as COSV56518890; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>C p.I1680T | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2, varscan2
- PLEKHH2 | c.3994G>C p.A1332P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV56750202; called by muse, mutect2, varscan2
- ROBO2 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100169946, COSV59899071, COSV59933610; called by muse, mutect2, varscan2
- SCNN1G | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs1335182657, COSV55597400; called by muse, mutect2, varscan2
- SERPINA10 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs768758518, COSV56227556; called by muse, mutect2, varscan2
- SUPT6H | c.3342+1G>A p.X1114_splice | Splice Site (SNP) | VAF 14/22 reads (64%) | catalogued as COSV58924885; called by muse, mutect2, varscan2
- TNRC6C | c.2299A>G p.T767A | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56940933; called by muse, mutect2, varscan2
- ZC3H18 | c.572A>C p.D191A | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56322791; called by muse, mutect2, varscan2
- DSG1 | c.844_845insTT p.T282Ifs*3 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by muse*, mutect2
- DSG1 | c.846_847insTACTTTATGACGGG p.L283Yfs*6 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel*
- KMT2D | c.9265del p.V3089Wfs*30 | Frame Shift Del (DEL) | VAF 46/113 reads (41%) | called by mutect2, pindel, varscan2
- N4BP3 | c.1107G>A p.E369= | Splice Region (SNP) | VAF 57/133 reads (43%) | called by muse, mutect2, varscan2
- RUNX1 | c.983_984insAA p.Y328* (on ENST00000344691 / NM_001001890.3; = p.Y355* on NM_001754.5) | Nonsense Mutation (INS) | VAF 35/94 reads (37%) | called by mutect2, pindel, varscan2
- SH3GL1 | c.475_483del p.K159_L161del | In Frame Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- TRGJP2 | c.1_2insACA p.*1_S2insH | In Frame Ins (INS) | VAF 37/41 reads (90%) | called by mutect2, pindel, varscan2
- BCR | c.1734C>T p.G578= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs373937043; called by muse, mutect2
- KLHL29 | c.234C>T p.S78= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs1483688653; called by muse, mutect2, varscan2
- PDE4D | c.390C>T p.T130= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs1298391358, COSV100506288; called by muse, mutect2, varscan2
- AUP1 | c.1077+83T>G | Intron (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.*175G>A | 3'UTR (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- CYB5B | c.-50G>C | 5'UTR (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
- LACTB2 | c.*18C>T | 3'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2
- PHC1P1 | n.505C>T | RNA (SNP) | VAF 44/112 reads (39%) | catalogued as rs917767312; called by muse, mutect2, varscan2
